CCDI case PBBVVP — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Thyroid gland.
https://portal.gdc.cancer.gov/cases/aa262722-4dd5-47f0-82bf-4f621331c3a5

Demographics
Sex at birth: female; Vital status: Alive.

Diagnoses (1)
1. Medullary carcinoma, NOS: ICD-O-3 morphology code: 8510/3; Tissue or organ of origin: Thyroid gland; Age at diagnosis: 13.3 years (4,870 days).

Biospecimens (2 samples)
- Sample 0DJHDV: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DJHGC: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
